Surgical pathology report (de-identified scan), TCGA case TCGA-22-5492, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-5492-01A (Primary Tumor).

DIAGNOSIS:

Lung, left upper lobe, lobectomy: Invasive grade 3 (of 4) squamous cell carcinoma forming a 4.5 x 4 x 3 cm intrabronchial and parenchymal hilar mass. Invasive carcinoma extends to within a few millimeters of the bronchial margin which is involved by extensive in situ carcinoma. The overlying pleura is retracted but tumor does not invade the pleura. The adjacent pulmonary parenchyma shows obstructive pneumonia.

Lymph nodes, intrapulmonary peribronchial, excision: Multiple intrapulmonary peribronchial (6 of 14) lymph nodes are involved by metastatic squamous cell carcinoma.

Lymph nodes, aortic, excision: Metastatic squamous cell carcinoma to (2 of 2) aortopulmonary and (1 of 2) anterior mediastinal lymph nodes.

Lymph nodes, superior mediastinal, inferior mediastinal and fissure, excision: Multiple lymph nodes (1 right lower paratracheal, 1 left lower paratracheal, 5 subcarinal, 1 inferior pulmonary ligament and 2 fissure) are negative for tumor.

Source: NCI Genomic Data Commons file 351cfba1-58c1-4160-80ea-6fd7d7d21c90 (TCGA-22-5492.D3432F86-2B6A-4C4B-81E5-827F8E5E918C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).